Somatic mutation profile of tumor specimen TCGA-ET-A3BO-01A (aliquot TCGA-ET-A3BO-01A-11D-A19J-08) from TCGA case TCGA-ET-A3BO, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, columnar cell; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 44.1 years (16,110 days).
Specimen TCGA-ET-A3BO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7314d93a-16c0-44fc-aaa0-5d853580373a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3BO-10A (Blood Derived Normal), aliquot TCGA-ET-A3BO-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/393f959e-9a24-4e87-874c-d963de681db9

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ERICH3 | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58599890; called by muse, mutect2
- H2AX | c.34C>A p.R12S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.924); catalogued as COSV53827608; called by muse, mutect2
- LTBP1 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | catalogued as COSV63180597; called by muse, mutect2
- TG | c.5928_5929dup p.S1977Yfs*37 | Frame Shift Ins (INS) | VAF 28/114 reads (25%) | called by mutect2, pindel, varscan2
- OR7A17 | c.120C>T p.L40= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as rs752784470, COSV59413837; called by muse, mutect2
